Somatic mutation profile of tumor specimen 0DIWMI from CCDI case PBBWFV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.9 years (3,240 days).
Specimen 0DIWMI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58dc86e8-5f80-44bf-bc09-5f29c734af06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIWMG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f039d38-b7d7-4cb3-8e76-9314e24cf480

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 2, 5'UTR 1, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4612-1G>A p.X1538_splice | Splice Site (SNP) | VAF 294/622 reads (47%) | catalogued as rs1555100351, COSV99587122; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.9023G>A p.R3008H | Missense Mutation (SNP) | VAF 387/1024 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587781894, CM092589, COSV53726175, COSV53741856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 466/955 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 213/484 reads (44%) | catalogued as rs1064797099, CM124484, COSV59954253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP001054.1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 103/267 reads (39%) | catalogued as rs376865084; called by muse, mutect2, varscan2
- CBY2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 204/451 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs540448583, COSV60118895; called by muse, mutect2, varscan2
- HSD17B2 | c.682A>G p.R228G | Missense Mutation (SNP) | VAF 568/1152 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52277692; called by muse, mutect2, varscan2
- LARP1 | c.940C>T p.P314S (on ENST00000518297 / NM_033551.3; = p.P237S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 286/648 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs763321852; called by muse, mutect2, varscan2
- PCDHB9 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV53375579, COSV53380716; called by muse, mutect2, varscan2
- PKDREJ | c.6378G>C p.Q2126H | Missense Mutation (SNP) | VAF 254/614 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53546741; called by muse, mutect2, varscan2
- SLC9A7 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 308/795 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049438872, COSV60381565; called by muse, mutect2, varscan2
- KLK2 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 219/460 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PIK3R1 | c.1350_1352del p.H450_E451delinsQ (on ENST00000521381 / NM_181523.3; = p.H180_E181delinsQ on NM_181504.4) | In Frame Del (DEL) | VAF 225/781 reads (29%) | called by mutect2, varscan2
- PTPRF | c.4940C>A p.A1647D | Missense Mutation (SNP) | VAF 229/664 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP6V1C1 | c.549C>T p.V183= | Silent (SNP) | VAF 548/1433 reads (38%) | catalogued as rs776546018; called by muse, mutect2, varscan2
- SPTBN1 | c.6762T>C p.P2254= | Silent (SNP) | VAF 625/1387 reads (45%) | called by muse, mutect2, varscan2
- C8orf34 | c.328-31A>G | Intron (SNP) | VAF 34/612 reads (6%) | catalogued as COSV61389548; called by muse, mutect2
- TRA2B | c.334-89G>A | Intron (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- USH2A | c.-60C>T | 5'UTR (SNP) | VAF 351/582 reads (60%) | catalogued as rs375409287, COSV56334842; called by muse, mutect2, varscan2
